Somatic mutation profile of tumor specimen TCGA-VS-A9UP-01A (aliquot TCGA-VS-A9UP-01A-11D-A42O-09) from TCGA case TCGA-VS-A9UP, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 43.4 years (15,849 days).
Specimen TCGA-VS-A9UP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e9c73c28-c2ec-4189-8860-b431902ca7c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A9UP-10A (Blood Derived Normal), aliquot TCGA-VS-A9UP-10A-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7fdd83de-6901-4525-978d-637865cfdbf8

The open-access MAF lists 201 somatic variants for this specimen: 148 protein-altering or splice-affecting, 46 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 118, Silent 46, Nonsense Mutation 20, Frame Shift Del 5, RNA 3, Splice Site 2, Intron 2, 5'UTR 1, In Frame Del 1, 3'UTR 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA1 | c.3718C>T p.Q1240* | Nonsense Mutation (SNP) | VAF 8/36 reads (22%) | catalogued as rs80356903, CM086783, COSV100523463, COSV58795672; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FSHB | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 12/28 reads (43%) | catalogued as rs374623109, COSV54221612; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.1658C>T p.S553L | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.223); catalogued as COSV100228617; called by muse, mutect2, varscan2
- ABCC1 | c.4290C>T p.L1430= | Splice Region (SNP) | VAF 10/26 reads (38%) | catalogued as COSV100578872; called by muse, mutect2, varscan2
- ACIN1 | c.2821G>A p.E941K | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.301); catalogued as COSV99399231; called by mutect2, varscan2
- ACTB | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.026); catalogued as COSV100079440; called by muse, mutect2, varscan2
- ALS2CL | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs535935636, COSV100014832; called by muse, mutect2, varscan2
- ANAPC13 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.187); catalogued as COSV59680020; called by muse, mutect2, varscan2
- ANKS1B | c.1228C>G p.P410A | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as COSV100243537; called by muse, mutect2, varscan2
- AP2B1 | c.1490C>T p.S497L | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV99250959; called by muse, mutect2, varscan2
- APLP1 | c.1645C>T p.R549* (on ENST00000221891 / NM_001024807.3; = p.R548* on NM_005166.4) | Nonsense Mutation (SNP) | VAF 6/66 reads (9%) | catalogued as rs776958157, COSV55701572, COSV55702466; called by mutect2, varscan2
- ARAF | c.532G>C p.E178Q | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.616); catalogued as COSV99283043; called by muse, mutect2, varscan2
- ARHGAP5 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100565076; called by muse, mutect2, varscan2
- ARMC4 | c.1318C>T p.R440C | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs376424270; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATG5 | c.712G>C p.V238L | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.137); catalogued as rs1356561310, COSV100576411; called by muse, varscan2
- ATP2A2 | c.1313G>C p.G438A | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100428461; called by muse, mutect2, varscan2
- BABAM2 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.982); catalogued as COSV100567453; called by muse, mutect2, varscan2
- BAHCC1 | c.5590G>T p.E1864* | Nonsense Mutation (SNP) | VAF 25/37 reads (68%) | catalogued as COSV100311274; called by muse, mutect2, varscan2
- BIRC6 | c.8483C>T p.T2828I | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.274); catalogued as rs776176230, COSV101427978; called by muse, mutect2, varscan2
- BLM | c.4162G>A p.A1388T | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.255); catalogued as COSV100757036; called by muse, mutect2, varscan2
- BMX | c.1687G>C p.D563H | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100564350; called by muse, mutect2, varscan2
- CACNA1C | c.5264C>T p.P1755L | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as rs755513147, COSV100216533, COSV59697431; called by muse, mutect2, varscan2
- CCR10 | c.291C>A p.F97L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV99226181; called by muse, mutect2, varscan2
- CDX4 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV100999112; called by muse, mutect2, varscan2
- CEP162 | c.649G>C p.E217Q | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.073); catalogued as COSV100002472; called by muse, mutect2, varscan2
- CHM | c.852C>A p.S284R | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100753085; called by muse, mutect2, varscan2
- CPXM2 | c.1408C>T p.Q470* | Nonsense Mutation (SNP) | VAF 12/26 reads (46%) | catalogued as rs201420520, COSV99581335; called by muse, mutect2, varscan2
- CRYGC | c.199C>T p.Q67* | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | catalogued as COSV99965257; called by muse, mutect2, varscan2
- CS | c.1374G>T p.M458I | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100369921; called by muse, mutect2, varscan2
- CSK | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.26); catalogued as rs780001574, COSV54972498; called by muse, mutect2, varscan2
- CTNND2 | c.1645G>C p.D549H | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100473168, COSV58888802; called by muse, mutect2, varscan2
- DHX9 | c.1367G>A p.R456Q | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100841212; called by muse, mutect2, varscan2
- DNAH11 | c.3320G>T p.S1107I | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV100177881, COSV100180818; called by muse, mutect2, varscan2
- DNAJC14 | c.1651C>T p.R551W | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs534529653, COSV99670666; called by muse, varscan2
- DRD5 | c.1372G>C p.D458H | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV100431607, COSV58580829; called by muse, mutect2, varscan2
- DSEL | c.2476C>A p.L826I | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.423); catalogued as rs200277299, COSV100025365, COSV59490306; called by muse, mutect2, varscan2
- EIF2AK1 | c.1726C>T p.Q576* | Nonsense Mutation (SNP) | VAF 13/36 reads (36%) | catalogued as COSV99551650; called by muse, mutect2, varscan2
- EPB41L5 | c.1900G>A p.E634K | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.214); catalogued as COSV99758404; called by muse, mutect2, varscan2
- FAM189A2 | c.715C>A p.P239T | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99974804; called by muse, mutect2, varscan2
- FAM72A | c.390G>C p.E130D | Missense Mutation (SNP) | VAF 124/357 reads (35%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV100367240; called by muse, mutect2, varscan2
- FBXO41 | c.1376G>T p.S459I | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as COSV99720985; called by muse, mutect2
- FGD6 | c.3802C>G p.Q1268E | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV100676426, COSV59698000; called by muse, mutect2, varscan2
- FLG | c.6524G>T p.G2175V | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV100910918, COSV64245100; called by muse, mutect2, varscan2
- FNIP2 | c.320C>G p.S107C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV100032290; called by muse, mutect2, varscan2
- FRAS1 | c.9158A>C p.E3053A | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99349258; called by muse, mutect2, varscan2
- FZD8 | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV101020197; called by muse, mutect2, varscan2
- GPR1 | c.526C>T p.R176W | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs202007589, COSV101329832; called by muse, mutect2, varscan2
- GPRASP2 | c.958A>G p.T320A | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0.012); catalogued as COSV100176591; called by muse, mutect2, varscan2
- GSS | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.988); catalogued as COSV99404268; called by muse, mutect2, varscan2
- HCN1 | c.253G>T p.E85* | Nonsense Mutation (SNP) | VAF 4/25 reads (16%) | catalogued as COSV57525598; called by muse, mutect2
- HIP1 | c.2503C>G p.Q835E | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV100417121; called by muse, mutect2
- HMCN1 | c.11378G>A p.R3793H | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs768205453, COSV54932305; called by muse, mutect2, varscan2
- IFI16 | c.893C>A p.A298E | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99857165; called by muse, mutect2, varscan2
- IGF2BP1 | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51736050; called by muse, mutect2, varscan2
- INPP1 | c.1072G>C p.E358Q | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV100487140; called by muse, mutect2, varscan2
- ITGA11 | c.1874G>C p.G625A | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100241117; called by muse, mutect2, varscan2
- KANSL1 | c.968G>A p.G323E | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99294183; called by muse, mutect2, varscan2
- KASH5 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.297); catalogued as rs756830729, COSV101483404; called by muse, mutect2, varscan2
- KIT | c.2637C>G p.F879L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99853533; called by muse, mutect2, varscan2
- KMT2C | c.3757G>C p.E1253Q | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100068708, COSV100069249; called by muse, mutect2, varscan2
- LMTK3 | c.3051G>C p.R1017S | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV99540082; called by muse, mutect2
- LTN1 | c.5284C>G p.R1762G | Missense Mutation (SNP) | VAF 61/136 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100797911, COSV63733341; called by muse, mutect2, varscan2
- MADD | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100211147; called by muse, mutect2, varscan2
- MAF1 | c.20C>A p.S7* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as COSV100075385; called by muse, mutect2, varscan2
- MAGEC2 | c.934A>T p.K312* | Nonsense Mutation (SNP) | VAF 15/36 reads (42%) | catalogued as COSV99909453; called by muse, mutect2, varscan2
- MAP3K19 | c.995C>G p.S332C | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV100208198, COSV59638694; called by muse, mutect2, varscan2
- MBTD1 | c.1404C>G p.D468E | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100899128; called by muse, mutect2, varscan2
- MDC1 | c.2414G>A p.R805K | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.287); catalogued as rs745970640, COSV100902659; called by muse, mutect2, varscan2
- MDC1 | c.1129G>C p.D377H | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100902661; called by muse, mutect2, varscan2
- MDC1 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV100902662, COSV64524134; called by muse, mutect2, varscan2
- MED26 | c.1513C>G p.P505A | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.473); catalogued as COSV99659847; called by muse, mutect2, varscan2
- MED26 | c.1130C>G p.S377C | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as COSV99659849; called by muse, mutect2, varscan2
- MMRN1 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1218992287, COSV99306665; called by muse, mutect2, varscan2
- MNDA | c.953G>A p.G318E | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142876368, COSV63740368; called by muse, mutect2, varscan2
- MPO | c.179C>G p.S60W | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV56561295, COSV99832376; called by mutect2, varscan2
- MYT1 | c.2014A>G p.S672G | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100114169; called by muse, varscan2
- NEB | c.19775C>T p.S6592F | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1337253481, COSV99416814; called by muse, mutect2, varscan2
- NPNT | c.72-2A>T p.X24_splice | Splice Site (SNP) | VAF 14/34 reads (41%) | catalogued as rs768395212, COSV99974799; called by muse, mutect2, varscan2
- NSF | c.1829-1G>C p.X610_splice | Splice Site (SNP) | VAF 15/63 reads (24%) | catalogued as COSV99833714; called by muse, mutect2, varscan2
- ONECUT2 | c.1487C>A p.S496Y | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.521); catalogued as COSV101525693; called by muse, mutect2, varscan2
- OR1B1 | c.511A>T p.T171S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV100506421; called by muse, mutect2
- OR1B1 | c.509G>A p.W170* | Nonsense Mutation (SNP) | VAF 6/15 reads (40%) | catalogued as COSV100506422; called by muse, mutect2
- OR9I1 | c.920G>A p.R307K | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV100109541; called by muse, mutect2, varscan2
- PALLD | c.2530C>T p.Q844* (on ENST00000505667 / NM_001166108.2; = p.Q827* on NM_016081.4) | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as COSV99824098; called by muse, mutect2, varscan2
- PDZRN3 | c.3013G>C p.E1005Q | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV99728007; called by muse, mutect2, varscan2
- PGAM2 | c.539G>A p.R180Q | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.044); catalogued as rs375305359, COSV99803760; called by muse, mutect2, varscan2
- PGAP3 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs532257048, COSV99510503; called by muse, mutect2, varscan2
- PIK3R4 | c.3613C>T p.Q1205* | Nonsense Mutation (SNP) | VAF 7/41 reads (17%) | catalogued as COSV100649966; called by muse, mutect2, varscan2
- PKD1 | c.1747C>G p.L583V | Missense Mutation (SNP) | VAF 51/207 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.084); catalogued as rs1567213948, COSV99237410; called by muse, mutect2, varscan2
- PLK2 | c.1961C>A p.T654N | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99955855; called by mutect2, varscan2
- PLXNB2 | c.3727G>A p.E1243K | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as COSV100833897, COSV100834043; called by muse, mutect2, varscan2
- PNISR | c.1449G>T p.K483N | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.62); catalogued as COSV100984325; called by muse, mutect2, varscan2
- POLR1G | c.827C>G p.T276S | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV99185231; called by muse, mutect2, varscan2
- POU4F2 | c.992G>A p.R331H | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs867084774, COSV55582937; called by muse, mutect2, varscan2
- PPFIA3 | c.1186G>C p.E396Q | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV100494757; called by muse, mutect2, varscan2
- PPFIA3 | c.1873G>T p.E625* | Nonsense Mutation (SNP) | VAF 36/131 reads (27%) | catalogued as COSV100494761; called by muse, mutect2, varscan2
- PPP2R3A | c.1863G>C p.M621I | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV99386598; called by muse, mutect2
- PRKAB1 | c.259G>T p.G87C | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs745730456, COSV57555254, COSV99982292; called by muse, mutect2, varscan2
- PROCR | c.377G>C p.R126T | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.103); catalogued as COSV99405699; called by muse, mutect2
- PROSER2 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs150713045; called by muse, mutect2, varscan2
- PTPRF | c.4077C>G p.I1359M | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV100740709; called by muse, mutect2, varscan2
- RALGAPB | c.4432G>C p.E1478Q | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1243086000, COSV99484858; called by muse, mutect2, varscan2
- RASSF6 | c.310C>G p.L104V (on ENST00000342081 / NM_201431.2; = p.L72V on NM_177532.5) | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100274812; called by muse, mutect2, varscan2
- RNF149 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0.018); catalogued as COSV99766466; called by muse, mutect2
- RNF180 | c.553G>T p.E185* | Nonsense Mutation (SNP) | VAF 7/23 reads (30%) | catalogued as COSV99684463; called by muse, mutect2, varscan2
- RPP30 | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV99520686; called by muse, mutect2, varscan2
- RUSC1 | c.127C>A p.P43T | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.878); catalogued as COSV99429558; called by muse, mutect2, varscan2
- SEMG2 | c.640C>T p.H214Y | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0.342); catalogued as COSV101033993; called by muse, mutect2
- SH3BP2 | c.897G>C p.E299D | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV100696883; called by muse, mutect2, varscan2
- SIX4 | c.754G>T p.E252* | Nonsense Mutation (SNP) | VAF 28/89 reads (31%) | catalogued as COSV53671756, COSV99382017; called by muse, mutect2, varscan2
- SOX5 | c.859C>T p.Q287* | Nonsense Mutation (SNP) | VAF 19/82 reads (23%) | catalogued as COSV100506229; called by muse, mutect2, varscan2
- SPTBN1 | c.1450G>A p.V484M | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV61694645; called by muse, mutect2
- SRSF4 | c.619C>T p.R207* | Nonsense Mutation (SNP) | VAF 9/47 reads (19%) | catalogued as COSV100861376; called by muse, mutect2, varscan2
- STARD8 | c.2837C>T p.P946L | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as rs748875358, COSV52924402; called by muse, mutect2, varscan2
- STYX | c.451C>G p.Q151E | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.729); catalogued as COSV100648270; called by muse, mutect2, varscan2
- SUPT5H | c.229C>G p.L77V | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.644); catalogued as COSV100781957; called by muse, mutect2, varscan2
- TAFA3 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100721450; called by muse, mutect2, varscan2
- TASP1 | c.235G>T p.G79C | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100534458; called by muse, mutect2, varscan2
- TEX13B | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.795); catalogued as COSV100258271; called by muse, mutect2, varscan2
- TIAM1 | c.712C>G p.Q238E | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as COSV99733473; called by muse, mutect2, varscan2
- TMEM47 | c.31G>A p.V11M | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.459); catalogued as COSV99327516; called by muse, mutect2, varscan2
- TNFAIP8 | c.205G>C p.E69Q | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.95); PolyPhen benign (0.058); catalogued as COSV99174230; called by muse, mutect2, varscan2
- TNIK | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.614); catalogued as rs774299223, COSV99455706; called by muse, mutect2, varscan2
- TNK2 | c.2556G>C p.K852N | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV57367160; called by muse, mutect2, varscan2
- TOPORS | c.1417G>A p.D473N | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as COSV100745139; called by muse, mutect2, varscan2
- TRAF2 | c.1435G>T p.E479* | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | catalogued as COSV99916285; called by muse, mutect2, varscan2
- TRERF1 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.877); catalogued as rs369100062; called by muse, mutect2, varscan2
- TSBP1 | c.1279G>T p.E427* (on ENST00000617061; = p.E432* on NM_006781.5) | Nonsense Mutation (SNP) | VAF 23/47 reads (49%) | catalogued as COSV100898731; called by muse, mutect2, varscan2
- TTN | c.75037G>A p.D25013N (on ENST00000591111; = p.D17589N on NM_003319.4) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | PolyPhen possibly damaging (0.848); catalogued as COSV100599437; called by mutect2, varscan2
- TXNDC2 | c.278C>T p.S93L (on ENST00000306084 / NM_001098529.2; = p.S26L on NM_032243.6) | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as COSV60153014; called by muse, mutect2, varscan2
- USP4 | c.1403C>A p.S468Y | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99649111; called by muse, mutect2, varscan2
- WDR73 | c.222C>G p.F74L | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV101272967, COSV68321235; called by muse, mutect2, varscan2
- XPR1 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs765277483, COSV62560099; called by muse, mutect2
- XRN1 | c.2029C>G p.Q677E | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.127); catalogued as COSV99377440; called by muse, mutect2, varscan2
- ZNF217 | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as rs1409216321, COSV56603576; called by muse, mutect2
- ZNF284 | c.775C>T p.H259Y | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV101398939; called by muse, mutect2, varscan2
- ZNF583 | c.859C>A p.Q287K | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.266); catalogued as COSV52404243, COSV99381990; called by muse, mutect2, varscan2
- ZNF862 | c.2051C>T p.P684L | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.637); catalogued as COSV56224798; called by muse, mutect2, varscan2
- ABHD3 | c.524_536del p.N175Rfs*7 | Frame Shift Del (DEL) | VAF 20/150 reads (13%) | called by mutect2, pindel
- ACAP3 | c.437_441del p.R146Pfs*38 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | called by mutect2, pindel, varscan2
- CGB2 | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); called by muse, mutect2
- DDX11 | c.1466_1468del p.N489del | In Frame Del (DEL) | VAF 12/73 reads (16%) | called by pindel, varscan2
- EXOC1 | c.1756_1760del p.I586Sfs*4 | Frame Shift Del (DEL) | VAF 9/34 reads (26%) | called by mutect2, pindel, varscan2
- GRM3 | c.949del p.A317Pfs*78 | Frame Shift Del (DEL) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- IGLV1-50 | c.251C>T p.S84F | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MORF4L2 | c.295_296insTAGATAACCTC p.R99Lfs*29 | Frame Shift Ins (INS) | VAF 8/45 reads (18%) | called by mutect2, pindel, varscan2
- PCOLCE2 | c.273_280del p.D92Qfs*35 | Frame Shift Del (DEL) | VAF 5/38 reads (13%) | called by mutect2, pindel, varscan2
- TRAV23DV6 | c.162G>C p.E54D | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AARS1 | c.1803C>T p.I601= | Silent (SNP) | VAF 28/50 reads (56%) | catalogued as COSV99933264; called by muse, mutect2, varscan2
- ABCC4 | c.297G>C p.T99= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs977021736, COSV100972322; called by muse, mutect2, varscan2
- ABCC5 | c.2454G>A p.K818= | Silent (SNP) | VAF 15/124 reads (12%) | catalogued as COSV99656553; called by muse, mutect2, varscan2
- ABCF3 | c.1455G>A p.E485= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as COSV99491300; called by muse, mutect2, varscan2
- ABHD1 | c.1182C>G p.L394= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV99574351; called by muse, mutect2, varscan2
- ADAMTS13 | c.4014C>A p.A1338= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV99390147; called by muse, mutect2, varscan2
- CCDC189 | c.990C>G p.T330= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV100079433; called by muse, mutect2, varscan2
- CDC25A | c.1200G>A p.V400= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as COSV100207370; called by muse, mutect2, varscan2
- CEP250 | c.6792G>A p.E2264= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV100698790; called by muse, mutect2, varscan2
- CHD6 | c.2721C>T p.L907= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as rs1486132170, COSV100497900; called by muse, mutect2, varscan2
- CNP | c.48C>A p.I16= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV101102889; called by muse, mutect2, varscan2
- ENY2 | c.99G>A p.L33= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV99516796; called by muse, mutect2, varscan2
- EPHB6 | c.2319G>A p.L773= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as COSV100844173; called by muse, mutect2, varscan2
- EPRS1 | c.2097G>A p.L699= | Silent (SNP) | VAF 24/79 reads (30%) | catalogued as COSV100859330; called by muse, mutect2, varscan2
- FAM83H | c.2811C>T p.L937= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs1357716592, COSV100567740; called by muse, mutect2, varscan2
- FCGBP | c.309C>T p.I103= | Silent (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2, varscan2
- FGF18 | c.294G>T p.R98= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV99208639; called by muse, mutect2, varscan2
- FMNL1 | c.2103G>A p.Q701= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs1203161923, COSV100056256; called by muse, mutect2, varscan2
- HIP1 | c.1944C>T p.I648= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV100417123; called by muse, mutect2, varscan2
- HOXC4 | c.693G>A p.A231= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV57699740; called by muse, mutect2, varscan2
- HP1BP3 | c.1653G>A p.V551= | Silent (SNP) | VAF 23/51 reads (45%) | catalogued as rs1317840168, COSV100391605; called by muse, mutect2, varscan2
- HS6ST3 | c.645C>T p.L215= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV100940122, COSV65014551; called by muse, mutect2
- ITPR1 | c.6720C>T p.I2240= (on ENST00000354582; = p.I2185= on NM_002222.7) | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV100230100, COSV100230224; called by muse, mutect2, varscan2
- MELTF | c.102C>T p.H34= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs943304669, COSV99585911; called by muse, mutect2
- MROH6 | c.285G>T p.G95= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as COSV99434460; called by muse, mutect2, varscan2
- MYH14 | c.3036C>T p.S1012= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV51811405; called by muse, mutect2, varscan2
- MYO18B | c.2269C>T p.L757= | Silent (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- MYT1 | c.1992C>T p.D664= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as rs776427915, COSV60515698; ClinVar: likely benign; called by muse, varscan2
- PCDHA2 | c.1161C>T p.C387= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs782297262, COSV100973676; called by muse, mutect2, varscan2
- PKP1 | c.462C>T p.R154= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs760911627, COSV99824992; called by muse, mutect2, varscan2
- POLR1G | c.724C>T p.L242= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV99185230; called by muse, mutect2, varscan2
- PPFIA3 | c.1386G>C p.L462= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs1353323542, COSV100494758; called by muse, varscan2
- PPFIA3 | c.1479G>A p.E493= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV100494760; called by muse, mutect2, varscan2
- PYGB | c.192C>A p.L64= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV53820419, COSV99404912; called by muse, mutect2, varscan2
- RBM4 | c.327C>A p.I109= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as rs868122464, COSV100029547, COSV59519455; called by muse, mutect2, varscan2
- ST3GAL1 | c.36C>T p.L12= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV100171887, COSV100171929; called by muse, varscan2
- STAP2 | c.861G>A p.P287= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs145032917, COSV99696649; called by muse, mutect2, varscan2
- STKLD1 | c.1689G>A p.V563= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV100905713; called by muse, mutect2, varscan2
- TES | c.1218A>C p.V406= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV100829235; called by muse, mutect2, varscan2
- TMPRSS11D | c.828G>A p.V276= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as rs888255537, COSV52221341, COSV52223952; called by muse, mutect2, varscan2
- TUBB6 | c.456C>A p.I152= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV99301613; called by muse, mutect2, varscan2
- UFC1 | c.96G>A p.L32= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as rs1363622290, COSV63500992; called by muse, mutect2, varscan2
- USP14 | c.741C>T p.F247= | Silent (SNP) | VAF 33/129 reads (26%) | catalogued as rs189562044, COSV99863872; called by muse, mutect2, varscan2
- ZMYM4 | c.3534G>A p.R1178= | Silent (SNP) | VAF 9/142 reads (6%) | catalogued as COSV100109690, COSV100111219; called by muse, mutect2
- ZNF135 | c.1500C>A p.G500= (on ENST00000313434 / NM_001289401.2; = p.G512= on NM_003436.4) | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV100536481; called by muse, mutect2, varscan2
- ZNF185 | c.105G>A p.L35= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV100248238; called by muse, mutect2, varscan2
- AC024940.1 | n.4581C>G | RNA (SNP) | VAF 24/107 reads (22%) | called by muse, mutect2, varscan2
- BIRC8 | n.1074C>T | RNA (SNP) | VAF 7/56 reads (13%) | catalogued as COSV101461299; called by muse, mutect2, varscan2
- BIRC8 | n.1073G>A | RNA (SNP) | VAF 6/55 reads (11%) | catalogued as rs1463011820, COSV101461300; called by muse, mutect2, varscan2
- CHD3 | c.4358+265C>T | Intron (SNP) | VAF 7/18 reads (39%) | catalogued as COSV100390850; called by muse, mutect2, varscan2
- FGFR1 | c.358+333T>G | Intron (SNP) | VAF 6/45 reads (13%) | called by muse, mutect2, varscan2
- TRDC | c.*88C>T | 3'UTR (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- YEATS2 | c.-1C>T | 5'UTR (SNP) | VAF 20/130 reads (15%) | catalogued as COSV100527575; called by muse, mutect2, varscan2
